Somatic mutation profile of tumor specimen MP2PRT-PASHUC-TBP1-A (aliquot MP2PRT-PASHUC-TBP1-A-1-0-D-A82A-36) from MP2PRT case MP2PRT-PASHUC, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.8 years (665 days).
Specimen MP2PRT-PASHUC-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) de31bd62-a6a5-4151-a911-3ed9b3e8c4d7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASHUC-NB1-B (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASHUC-NB1-B-1-0-D-A82A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c41f31f0-27ce-40c2-98f6-dbbfa6c10fea

The open-access MAF lists 12 somatic variants for this specimen: 7 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 6, Silent 5, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SAGE1 | c.2506C>G p.R836G | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV61012285; called by muse, mutect2, varscan2
- TSPOAP1 | c.3341C>T p.S1114F | Missense Mutation (SNP) | VAF 151/799 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV52106994; called by muse, mutect2, varscan2
- FRY | c.244A>T p.I82F | Missense Mutation (SNP) | VAF 47/311 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- GRIA1 | c.69C>A p.N23K | Missense Mutation (SNP) | VAF 42/536 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2
- ISL1 | c.340C>G p.L114V | Missense Mutation (SNP) | VAF 25/882 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.434); called by muse, mutect2
- OR10T2 | c.832_833delinsCCTCCC p.Y278Pfs*10 | Frame Shift Ins (INS) | VAF 71/354 reads (20%) | called by pindel, varscan2*
- WNT2 | c.953T>C p.V318A | Missense Mutation (SNP) | VAF 57/594 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- BCAR1 | c.2457G>C p.L819= | Silent (SNP) | VAF 32/752 reads (4%) | called by muse, mutect2
- BEND2 | c.2292C>T p.D764= | Silent (SNP) | VAF 133/714 reads (19%) | catalogued as rs367620811, COSV66220307; called by muse, mutect2, varscan2
- CTSG | c.543C>G p.P181= | Silent (SNP) | VAF 49/636 reads (8%) | catalogued as rs1250049373; called by muse, mutect2
- LCA5 | c.1791A>G p.R597= | Silent (SNP) | VAF 48/284 reads (17%) | called by muse, mutect2, varscan2
- PCDHGA6 | c.1935C>T p.A645= | Silent (SNP) | VAF 109/1039 reads (10%) | catalogued as rs761668305; called by muse, mutect2, varscan2
